MMRF case MMRF_2107 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/3f80c201-c9bb-46b8-ade1-ad047574a553

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 63 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 63.6 years (23,217 days); ISS stage: I; Days to last known disease status: 829 days (2.3 years); Days to last follow up: 829 days (2.3 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 829.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -2 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 849 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.45 mg/dL; Immunoglobulin G 4.8 g/L; Immunoglobulin A 0.6 g/L; Immunoglobulin M 0.14 g/L; Beta 2 Microglobulin 2.37 µg/mL; Lactate Dehydrogenase 2.92 µkat/L; Hemoglobin 8.37 mmol/L; Leukocytes 6.4 ×10⁹/L; Absolute Neutrophil 3.9 ×10⁹/L; Platelets 345 ×10⁹/L; Creatinine 48.6 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.75 mmol/L; Albumin 46 g/L; Total Protein 6.9 g/dL; Glucose 4.62 mmol/L; C-Reactive Protein 0.18 mg/dL.
- Day 85 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.691 mg/dL; Immunoglobulin G 4.17 g/L; Immunoglobulin A 0.58 g/L; Immunoglobulin M 0.18 g/L; Lactate Dehydrogenase 3.5 µkat/L; Hemoglobin 8.06 mmol/L; Leukocytes 5.9 ×10⁹/L; Absolute Neutrophil 5.4 ×10⁹/L; Platelets 471 ×10⁹/L; Creatinine 58.3 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.55 mmol/L; Albumin 42 g/L; Total Protein 6.4 g/dL; Glucose 6 mmol/L.
- Day 159 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.881 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.515 mg/dL; Immunoglobulin G 3.1 g/L; Immunoglobulin A 0.6 g/L; Immunoglobulin M 0.16 g/L; Lactate Dehydrogenase 3 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 2.5 ×10⁹/L; Absolute Neutrophil 1.3 ×10⁹/L; Platelets 314 ×10⁹/L; Creatinine 64.5 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.28 mmol/L; Albumin 40 g/L; Total Protein 5.96 g/dL; Glucose 5.01 mmol/L.
- Day 276 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.588 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.735 mg/dL; Immunoglobulin G 3.7 g/L; Immunoglobulin A 0.53 g/L; Immunoglobulin M 0.31 g/L; Beta 2 Microglobulin 1.24 µg/mL; Lactate Dehydrogenase 2.97 µkat/L; Hemoglobin 8.06 mmol/L; Leukocytes 8.9 ×10⁹/L; Absolute Neutrophil 6.4 ×10⁹/L; Platelets 241 ×10⁹/L; Creatinine 57.5 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.2 mmol/L; Albumin 35 g/L; Total Protein 5.7 g/dL; Glucose 4.79 mmol/L.
- Day 373 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.73 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.855 mg/dL; Immunoglobulin G 3.48 g/L; Immunoglobulin A 0.59 g/L; Immunoglobulin M 0.18 g/L; Lactate Dehydrogenase 3.2 µkat/L; Hemoglobin 8 mmol/L; Leukocytes 2.6 ×10⁹/L; Absolute Neutrophil 1.43 ×10⁹/L; Platelets 179 ×10⁹/L; Creatinine 58.3 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.38 mmol/L; Albumin 37 g/L; Total Protein 5.8 g/dL; Glucose 4.57 mmol/L.
- Day 549 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.749 mg/dL; Immunoglobulin G 4.17 g/L; Immunoglobulin A 0.62 g/L; Immunoglobulin M 0.19 g/L; Beta 2 Microglobulin 1.02 µg/mL; Lactate Dehydrogenase 3.28 µkat/L; Hemoglobin 7.56 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 1.87 ×10⁹/L; Platelets 169 ×10⁹/L; Creatinine 55.7 µmol/L; Blood Urea Nitrogen 8.93 mmol/L; Calcium 2.18 mmol/L; Albumin 37 g/L; Total Protein 5.5 g/dL; Glucose 4.57 mmol/L.
- Day 737: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.669 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.561 mg/dL; Immunoglobulin G 4.63 g/L; Immunoglobulin A 0.83 g/L; Immunoglobulin M 0.24 g/L; Beta 2 Microglobulin 0.99 µg/mL; Lactate Dehydrogenase 3.33 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 3.8 ×10⁹/L; Platelets 218 ×10⁹/L; Creatinine 53.9 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.45 mmol/L; Albumin 41 g/L; Total Protein 5.4 g/dL; Glucose 5.39 mmol/L.

Other clinical attributes
- Day -2: Weight: 76 kg; Height: 174 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_2107_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -2 days.
- Sample MMRF_2107_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -2 days.
